Gene-level copy-number profile of tumor specimen TCGA-RC-A6M6-01A from TCGA case TCGA-RC-A6M6, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 75.7 years (27,649 days).
Specimen TCGA-RC-A6M6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.468a304d-ff29-42a9-a75e-d64408fe1956.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-RC-A6M6-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6cabc83d-13ed-48d3-a4b1-05754817f88d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 18; copy number 1: 10,653; copy number 2: 42,489; copy number 3: 4,673; copy number 4: 1,469; copy number 5: 224; copy number 6: 61; copy number 7: 77; copy number 8: 39; copy number 10: 4; copy number 11: 48; copy number 13: 16; copy number 15: 11; copy number 19: 10; copy number 21: 5; copy number 24: 14.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-RC-A6M6-01A-11D-A32F-01): tumor purity 0.77, ploidy 2.05, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 11 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:34,488,583–34,488,878, 1 gene: ELOBP4.
- chr21:15,928,296–16,645,467, 1 gene (within-gene range 0–1): MIR99AHG.
- chr21:16,284,696–16,590,325, 9 genes: SNORD74B, AP001172.1, AP001172.2, AP000962.3, AP000962.2, MIR99A, MIRLET7C, AP000962.1, MIR125B2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 509 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:95,471,835–96,859,618, 16 genes, copy number 13: AC004012.1, ASB4, AC002451.2, AC002451.1, PDK4, DYNC1I1, AC002540.1, SLC25A13, MIR591, AC096775.1, AC084368.1, RNU6-532P, RNU6-364P, RNU7-188P, SEM1, MARK2P10.
- chr7:106,774,955–107,564,261, 10 genes, copy number 19 (within-gene range 4–19): LINC02577, RNA5SP236, PIK3CG, PRKAR2B, PRKAR2B-AS1, HBP1, AC004492.1, COG5, AC002381.1, GPR22.
- chr7:108,470,417–123,749,003, 179 genes, copy number 5–24 (within-gene range 2–24) (broad region; genes not listed).
- chr7:135,774,521–135,977,359, 3 genes, copy number 8 (within-gene range 2–8): AC015987.1, MTPN, RNU6-223P.
- chr7:137,227,341–137,354,483, 4 genes, copy number 10 (within-gene range 2–10): PTN, SNORD81, AC078842.2, AC078842.1.
- chr8:41,803,349–41,840,339, 3 genes, copy number 5: Y_RNA, AC027702.1, RN7SL149P.
- chr8:93,857,807–95,811,254, 48 genes, copy number 5 (within-gene range 4–5): PDP1, MIR378D2HG, MIR378D2, PSMA2P2, RPL34P18, AC105081.1, AP003351.1, CDH17, AP003478.1, GEM, RPS4XP10, RAD54B, FSBP, VIRMA, AC023632.5, AC023632.2, AC023632.1, AC023632.3, AC023632.4, AC108860.2, ESRP1, Metazoa_SRP, AC108860.1, AP005660.1, Y_RNA, DPY19L4, AP003692.1, INTS8, CCNE2, AC087752.4, AC087752.1, NDUFAF6, TP53INP1, AC087752.3, AC087752.2, AC068189.2, RNU6-1209P, MIR3150BHG, AC068189.1, MIR3150B, MIR3150A, PLEKHF2, C8orf37-AS1, LINC01298, C8orf37, AC024995.1, AC083836.1, RNU6-690P.
- chr8:142,834,138–145,066,685, 142 genes, copy number 5–8 (broad region; genes not listed).
- chr18:29,048,620–29,650,440, 5 genes, copy number 5: RNU6-408P, AC105245.1, AC074237.1, AC117569.1, AC117569.2.
- chr18:33,851,100–44,679,717, 99 genes, copy number 5–6 (within-gene range 3–6) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 10,619. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
